Somatic mutation profile of tumor specimen ALCH-AENX-TTP1-A (aliquot ALCH-AENX-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AENX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.5 years (21,371 days).
Specimen ALCH-AENX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a71d6a6-abc5-4b5d-98f0-69e94b2b9333.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AENX-NB1-A (Blood Derived Normal), aliquot ALCH-AENX-NB1-A-1-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8aeae99-0723-4f7d-8499-ea365e17475e

The open-access MAF lists 15 somatic variants for this specimen: 5 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 9, Missense Mutation 4, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX24 | c.2246A>G p.N749S | Missense Mutation (SNP) | VAF 10/239 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV99180177; called by muse, mutect2
- ATRNL1 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 16/441 reads (4%) | called by muse, mutect2
- FRAS1 | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RPLP1 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 15/320 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.35); called by muse, mutect2
- SLC2A9 | c.1219C>A p.H407N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATXN3L | c.489T>C p.F163= | Silent (SNP) | VAF 62/335 reads (19%) | called by muse, mutect2, varscan2
- GSS | c.912T>C p.T304= | Silent (SNP) | VAF 24/209 reads (11%) | called by muse, mutect2, varscan2
- HDLBP | c.2847C>T p.D949= | Silent (SNP) | VAF 25/216 reads (12%) | called by muse, mutect2, varscan2
- HIVEP2 | c.3318G>A p.E1106= | Silent (SNP) | VAF 15/297 reads (5%) | called by muse, mutect2
- NEB | c.7743C>G p.A2581= | Silent (SNP) | VAF 77/478 reads (16%) | called by muse, mutect2, varscan2
- NOL4L | c.708G>A p.K236= | Silent (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- OBSCN | c.21816G>A p.E7272= | Silent (SNP) | VAF 34/158 reads (22%) | called by muse, mutect2, varscan2
- PRKAG3 | c.81C>T p.S27= | Silent (SNP) | VAF 93/441 reads (21%) | catalogued as rs750890249; called by muse, mutect2, varscan2
- SIGLEC8 | c.654C>T p.H218= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as rs776383976; called by muse, mutect2, varscan2
- KIF3C | c.2007-8274C>T | Intron (SNP) | VAF 16/64 reads (25%) | catalogued as rs1260393803; called by muse, mutect2, varscan2
